Surgical pathology report (de-identified scan), TCGA case TCGA-4V-A9QL, project TCGA-THYM (Thymoma), tissue source site Hospital Louis Pradel, specimen TCGA-4V-A9QL-01A (Primary Tumor).

Macroscopic examination :

- 1 . A piece of thymectomy weighing 173 g and measuring 18 x 11 x 0.5 cm and having a nodule 8 x 7.5 x 4.3 cm surrounded by a capsule . When cut , the tumor appears lobulated without cyst , or necrosis , or bleeding .
- 2 . Two fragments of fat superior mediastinum measuring 2 and 2.2 cm long axis .
- 3 . A fragment of fat under left pleural measuring 3 x 2.5 x 2.5 cm.

ICD O-3
Thymoma, type AB NOS 8582/3
Site: Thymoma C37.9
Q616/14

Histopathological examination :

1 . thymus :

The tumor appears lobulated by thick fibrous tract from the capsule. It is constituted by a biphasic proliferation constituted firstly by cells quite numerous epithelial , spindled , grouped in small short beams with little nuclear atypia . The epithelial proliferation is associated with a lymphocytic component. Lymphocytes are quite small , regular . The tumor is surrounded by a thick fibrous capsule , not crossed. The normal thymus contains a discrete lymphoid hyperplasia, and extends in the medium mediastinum.

After immunohistochemistry , the tumor cells express pancytokeratin AE1/AE3 and focally CD20. They do not express CD5 or EMA. Lymphocytes are T phenotype of immature CD1a and CD3 + .

2 . Fat upper mediastinum :

The upper mediastinal fat is the location of two small lymph nodes lack of histopathological evidence of malignancy.

3 . Subcutaneous fat left pleural :

Fragment of connective adipose tissue without lymphoid structure.

Conclusion :

Thymoma 8 cm long axis , sub type AB , completely encapsulated . Resection is complete.

Source: NCI Genomic Data Commons file 0ceac370-5af9-471b-a382-19abc21118c0 (TCGA-4V-A9QL.2126DC95-17BF-4B43-A168-6930FC2ACD52.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).